Somatic mutation profile of tumor specimen MP2PRT-PAVPJN-TMP1-A (aliquot MP2PRT-PAVPJN-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAVPJN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.8 years (3,566 days).
Specimen MP2PRT-PAVPJN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 81979253-c333-4853-955d-def80a09d910.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVPJN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVPJN-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ec94d58-ab2d-4430-80ea-afc00e0845ac

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 3, Nonsense Mutation 1, 5'Flank 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 102/172 reads (59%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.845G>C p.R282P | Missense Mutation (SNP) | VAF 241/325 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs730882008, CM004344, COSV52689673, COSV52773873, COSV52969460, COSV53068318; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 22/376 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- GALNT18 | c.667G>A p.V223M | Missense Mutation (SNP) | VAF 73/383 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368911998; called by muse, mutect2, varscan2
- MATN4 | c.1225G>A p.V409M (on ENST00000372754; = p.V368M on NM_003833.4) | Missense Mutation (SNP) | VAF 144/469 reads (31%) | PolyPhen probably damaging (1); catalogued as rs778757225, COSV100637098; called by muse, mutect2, varscan2
- RBP5 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 66/364 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs150021847, COSV99870329; called by muse, mutect2, varscan2
- SNX19 | c.2780G>A p.G927E | Missense Mutation (SNP) | VAF 127/252 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99773075; called by muse, mutect2, varscan2
- EML6 | c.5658C>G p.N1886K | Missense Mutation (SNP) | VAF 89/391 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- GOLGA6D | c.607C>A p.Q203K | Missense Mutation (SNP) | VAF 75/355 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- HLX | c.743T>C p.V248A | Missense Mutation (SNP) | VAF 137/350 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- IGHV1-69 | c.338_346delinsGTGAGAGCCC p.Y113Cfs*? | Frame Shift Ins (INS) | VAF 30/98 reads (31%) | called by muse*, pindel
- IL7R | c.652A>G p.S218G | Missense Mutation (SNP) | VAF 85/294 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRDM9 | c.1116del p.K372Nfs*36 | Frame Shift Del (DEL) | VAF 148/343 reads (43%) | called by mutect2, pindel, varscan2
- RBM15 | c.1948G>T p.G650* | Nonsense Mutation (SNP) | VAF 25/578 reads (4%) | called by muse, mutect2
- TMEM94 | c.3544T>G p.S1182A | Missense Mutation (SNP) | VAF 115/601 reads (19%) | SIFT tolerated (0.77); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TULP1 | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 15/515 reads (3%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2
- OLFM4 | c.1380C>T p.N460= | Silent (SNP) | VAF 12/312 reads (4%) | called by muse, mutect2
- RTN1 | c.1413C>T p.C471= | Silent (SNP) | VAF 116/576 reads (20%) | catalogued as rs76760932; called by muse, mutect2, varscan2
- WFDC3 | c.594C>T p.G198= | Silent (SNP) | VAF 15/542 reads (3%) | called by muse, mutect2
- SPRTN | chr1:231338165 ins T | 5'Flank (INS) | VAF 46/433 reads (11%) | catalogued as rs1558359486; called by mutect2, varscan2
